Somatic mutation profile of tumor specimen TCGA-CV-5432-01A (aliquot TCGA-CV-5432-01A-02D-1683-08) from TCGA case TCGA-CV-5432, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 68.5 years (25,006 days).
Specimen TCGA-CV-5432-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92941587-c2b9-46df-8bed-036a53f6e52d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-5432-10A (Blood Derived Normal), aliquot TCGA-CV-5432-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e144207-d464-40ef-85cd-e35366b3b09b

The open-access MAF lists 275 somatic variants for this specimen: 199 protein-altering or splice-affecting, 73 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 172, Silent 73, Nonsense Mutation 14, Splice Site 9, Splice Region 2, Intron 1, RNA 1, Frame Shift Del 1, In Frame Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 5/13 reads (38%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.919+1G>T p.X307_splice | Splice Site (SNP) | VAF 77/99 reads (78%) | hotspot (GDC flag); catalogued as rs1131691039, CD920913, CS107068, CS120864, COSV52683145, COSV52775982, COSV52814989; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.1009C>A p.L337I | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.074); catalogued as rs757669020, COSV99446012; called by muse, mutect2, varscan2
- AC098582.1 | c.2519A>G p.D840G | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99985386; called by muse, mutect2, varscan2
- ACAD10 | c.2500C>A p.R834S | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV100563903; called by muse, mutect2, varscan2
- ADAMTS12 | c.2203G>T p.E735* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100710432, COSV61271652; called by muse, mutect2, varscan2
- ADAMTS14 | c.701C>G p.P234R | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as rs1204485333, COSV100941444, COSV64600227; called by mutect2, varscan2
- ADAMTS20 | c.2404A>T p.N802Y | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101166108; called by muse, mutect2, varscan2
- ADGRG2 | c.1940T>C p.L647P (on ENST00000379869 / NM_001079858.3; = p.L644P on NM_005756.4) | Missense Mutation (SNP) | VAF 59/92 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100491991; called by muse, mutect2, varscan2
- AGTR1 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 77/110 reads (70%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100836957, COSV62557553; called by muse, mutect2, varscan2
- AKIRIN2 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as COSV100005179; called by muse, mutect2, varscan2
- AMOT | c.2110G>T p.A704S (on ENST00000371959 / NM_001113490.1; = p.A295S on NM_133265.3) | Missense Mutation (SNP) | VAF 85/139 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs771142324, COSV59070549; called by muse, mutect2, varscan2
- AMOTL2 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.728); catalogued as COSV99998060; called by muse, mutect2, varscan2
- AP2A1 | c.2309G>T p.R770L | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV100571037; called by muse, mutect2, varscan2
- ARFGEF1 | c.1414A>T p.R472W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99141371; called by muse, mutect2, varscan2
- ASCC3 | c.5980G>T p.E1994* | Nonsense Mutation (SNP) | VAF 47/83 reads (57%) | catalogued as COSV100976297; called by muse, mutect2
- ASMTL | c.499G>T p.G167W | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV101187709; called by muse, mutect2
- ASTN2 | c.2368C>T p.Q790* (on ENST00000313400 / NM_001365069.1; = p.Q739* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 60/126 reads (48%) | catalogued as COSV57771951; called by muse, mutect2, varscan2
- BAZ1A | c.1447C>T p.Q483* | Nonsense Mutation (SNP) | VAF 16/107 reads (15%) | catalogued as COSV100701102; called by muse, mutect2, varscan2
- BICC1 | c.2023G>A p.D675N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.101); catalogued as COSV99570318; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2393C>G p.T798S | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100863640; called by muse, mutect2, varscan2
- C8orf34 | c.1233G>T p.R411S | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100297739; called by muse, mutect2, varscan2
- CADM2 | c.515T>G p.L172* (on ENST00000407528 / NM_001167674.2; = p.L174* on NM_153184.4) | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV101053360; called by muse, mutect2
- CALCR | c.181C>T p.Q61* | Nonsense Mutation (SNP) | VAF 70/243 reads (29%) | catalogued as COSV100810436; called by muse, mutect2, varscan2
- CAMTA2 | c.1403C>A p.S468* | Nonsense Mutation (SNP) | VAF 25/113 reads (22%) | catalogued as COSV100772498; called by muse, mutect2, varscan2
- CAND1 | c.2001A>T p.K667N | Missense Mutation (SNP) | VAF 84/115 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV101607300; called by muse, mutect2, varscan2
- CAPN10 | c.358G>T p.V120L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); catalogued as COSV99550028; called by muse, mutect2, varscan2
- CAPZB | c.202G>T p.G68W | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99939692; called by muse, mutect2, varscan2
- CBLN4 | c.347G>C p.R116T | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.908); catalogued as COSV50354316, COSV99290416; called by muse, mutect2, varscan2
- CCDC9 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99699568; called by muse, mutect2, varscan2
- CD1E | c.162G>C p.E54D | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100936937; called by muse, mutect2, varscan2
- CDK12 | c.4042T>C p.F1348L (on ENST00000447079 / NM_016507.4; = p.F1339L on NM_015083.3) | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.026); catalogued as COSV101420388; called by muse, mutect2
- CHML | c.269G>C p.R90P | Missense Mutation (SNP) | VAF 91/252 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV100087134; called by muse, mutect2, varscan2
- CIITA | c.443C>A p.P148Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV100161530; called by muse, mutect2, varscan2
- CNNM4 | c.1828G>T p.D610Y | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100998617, COSV65660189; called by muse, mutect2, varscan2
- CNTNAP5 | c.1325G>A p.G442D | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1283960552, COSV101443143; called by muse, mutect2, varscan2
- COL11A1 | c.890A>T p.Q297L | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as COSV100615473; called by muse, mutect2, varscan2
- COL15A1 | c.2423T>A p.I808N | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.099); catalogued as COSV100897500; called by muse, mutect2, varscan2
- COL22A1 | c.3502-2A>C p.X1168_splice | Splice Site (SNP) | VAF 63/207 reads (30%) | catalogued as COSV100276899; called by muse, mutect2, varscan2
- COL4A4 | c.2185G>T p.D729Y | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV100306403; called by muse, mutect2, varscan2
- COL5A3 | c.1348G>T p.A450S | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.058); catalogued as COSV99318367; called by muse, mutect2, varscan2
- CR1 | c.2576G>T p.W859L | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100887430; called by muse, mutect2, varscan2
- CREBBP | c.4841C>T p.S1614F | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV99269007; called by muse, mutect2, varscan2
- CUL3 | c.1486-1G>T p.X496_splice | Splice Site (SNP) | VAF 18/79 reads (23%) | catalogued as COSV100023915; called by muse, mutect2, varscan2
- DBX2 | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as COSV100224234; called by muse, mutect2, varscan2
- DCAF5 | c.881A>G p.Y294C | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100432298; called by muse, mutect2, varscan2
- DNAH5 | c.4825C>T p.Q1609* | Nonsense Mutation (SNP) | VAF 50/190 reads (26%) | catalogued as COSV99446276; called by muse, varscan2
- DPCD | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV100924231; called by muse, mutect2, varscan2
- DPP10 | c.370A>T p.T124S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0.028); catalogued as rs760689853, COSV100060490; called by muse, mutect2
- DPP10 | c.707T>A p.L236Q | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100060493; called by muse, mutect2, varscan2
- DPPA2 | c.583A>G p.R195G | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs765817808, COSV101524744; called by muse, mutect2, varscan2
- DSG3 | c.2257A>T p.T753S | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT tolerated (0.66); PolyPhen benign (0.043); catalogued as COSV99933881; called by muse, mutect2, varscan2
- DST | c.20820G>T p.W6940C (on ENST00000361203 / NM_001374722.1; = p.W4637C on NM_015548.5) | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99752507; called by muse, mutect2, varscan2
- EHBP1 | c.2179G>T p.D727Y | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); catalogued as COSV50431315; called by muse, mutect2, varscan2
- EPHA3 | c.88+1G>C p.X30_splice | Splice Site (SNP) | VAF 16/53 reads (30%) | catalogued as COSV100343683; called by muse, mutect2, varscan2
- EPN3 | c.1247C>G p.P416R | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV99276765; called by muse, mutect2, varscan2
- EVC | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99381317; called by muse, mutect2, varscan2
- FAM43A | c.1171A>T p.S391C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100316386; called by muse, mutect2, varscan2
- FAM47C | c.1999C>T p.P667S | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.43); PolyPhen benign (0.113); catalogued as rs781969441, COSV63724434; called by muse, mutect2, varscan2
- FBN1 | c.6913G>T p.G2305W | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100354182; called by muse, mutect2, varscan2
- FCRL4 | c.956C>G p.T319S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as COSV99619406; called by muse, mutect2, varscan2
- FGD1 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100910879; called by muse, mutect2, varscan2
- FIGN | c.401G>C p.G134A | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.434); catalogued as COSV100291785; called by muse, mutect2, varscan2
- FLG | c.3807T>A p.S1269R | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.966); catalogued as COSV100910975; called by muse, mutect2, varscan2
- FN1 | c.6512T>C p.I2171T (on ENST00000359671 / NM_001365524.2; = p.I2140T on NM_002026.4) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as rs1351159945, COSV100116464; called by muse, mutect2, varscan2
- FSCB | c.154T>C p.S52P | Missense Mutation (SNP) | VAF 74/259 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100468989; called by muse, mutect2, varscan2
- FSIP2 | c.20269C>A p.P6757T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100554393; called by muse, mutect2, varscan2
- GALNT13 | c.1459C>T p.L487F | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.192); catalogued as COSV67221656; called by muse, mutect2, varscan2
- GDAP1L1 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as rs375408909, COSV100697498; called by muse, varscan2
- GPATCH2L | c.670A>C p.S224R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99833441; called by muse, mutect2, varscan2
- GPR26 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV99500787; called by muse, mutect2, varscan2
- GPR37 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100390625; called by muse, mutect2, varscan2
- GRID2 | c.348C>A p.H116Q | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99938516; called by muse, mutect2, varscan2
- HERC2 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs558280248; called by muse, mutect2
- HGF | c.1631A>T p.Y544F | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV99735980; called by muse, mutect2, varscan2
- HOOK3 | c.992G>A p.G331D | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.438); catalogued as COSV100295167; called by muse, mutect2, varscan2
- HRNR | c.2506G>T p.G836C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV100913093; called by muse, mutect2, varscan2
- IFI27L1 | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.537); catalogued as COSV101267207; called by muse, mutect2, varscan2
- IL16 | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100267191; called by muse, mutect2
- IL1RAP | c.1545G>T p.K515N | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV99299196; called by muse, mutect2, varscan2
- INPP5A | c.735G>A p.T245= | Splice Region (SNP) | VAF 8/31 reads (26%) | catalogued as rs746139002, COSV100704201; called by muse, mutect2, varscan2
- IPO9 | c.565A>G p.I189V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as COSV100843361; called by muse, mutect2, varscan2
- ITGA8 | c.1696C>A p.R566S | Missense Mutation (SNP) | VAF 127/195 reads (65%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.536); catalogued as COSV100958987; called by muse, mutect2, varscan2
- ITGA8 | c.948+1G>A p.X316_splice | Splice Site (SNP) | VAF 14/25 reads (56%) | catalogued as rs1438235799, COSV100958990; called by muse, mutect2, varscan2
- ITGB8 | c.128-2A>T p.X43_splice | Splice Site (SNP) | VAF 13/18 reads (72%) | catalogued as COSV99750859; called by muse, mutect2, varscan2
- ITPR2 | c.3326A>G p.Y1109C | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67271717; called by muse, mutect2
- IVD | c.1222G>T p.G408W (on ENST00000651168; = p.G405W on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99991387; called by muse, mutect2, varscan2
- KCND2 | c.962C>G p.A321G | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100474245; called by muse, mutect2, varscan2
- KCNG3 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100044824; called by muse, mutect2, varscan2
- KIAA1328 | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV99693548; called by muse, mutect2
- KIAA1328 | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV99693552; called by muse, mutect2, varscan2
- KLHL42 | c.1268C>T p.T423I | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV101179710; called by mutect2, varscan2
- LPA | c.4720T>C p.C1574R | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338086573, COSV100306332; called by muse, mutect2, varscan2
- LRFN5 | c.519G>T p.L173F | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99982840; called by muse, mutect2, varscan2
- LRFN5 | c.976A>T p.K326* | Nonsense Mutation (SNP) | VAF 18/184 reads (10%) | catalogued as COSV99982841; called by muse, mutect2, varscan2
- LRP12 | c.507T>A p.D169E | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.301); catalogued as COSV99407357; called by muse, mutect2, varscan2
- LRP1B | c.2893C>A p.P965T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as COSV101253958, COSV101259775; called by muse, mutect2, varscan2
- MACROD2 | c.259A>G p.I87V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as rs778399330, COSV99428459; called by muse, mutect2, varscan2
- MAGEE2 | c.865C>A p.L289M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as COSV100973014; called by muse, mutect2, varscan2
- MEGF8 | c.5420A>T p.D1807V (on ENST00000251268 / NM_001271938.2; = p.D1740V on NM_001410.3) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.305); catalogued as COSV99234947; called by muse, mutect2, varscan2
- MFN2 | c.1268C>T p.T423M | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as rs8192303, COSV99336578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MIS18A | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99266978; called by muse, mutect2, varscan2
- MLH1 | c.413C>G p.P138R | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs1178996479, CD105398, COSV99212354, COSV99212396; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTIF2 | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs188291557, COSV55050625; called by muse, mutect2, varscan2
- MUC16 | c.24965C>A p.T8322N | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.251); catalogued as COSV101198707; called by muse, mutect2, varscan2
- MUC17 | c.6940A>G p.T2314A | Missense Mutation (SNP) | VAF 124/272 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100072142; called by muse, mutect2, varscan2
- MYF5 | c.82T>A p.F28I | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV99953185; called by muse, mutect2, varscan2
- MYOM1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55287221; called by muse, mutect2, varscan2
- MYOM2 | c.3043+1G>A p.X1015_splice | Splice Site (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100036955; called by muse, mutect2, varscan2
- N4BP2 | c.851T>C p.V284A | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV99788318; called by muse, mutect2, varscan2
- NCBP2L | c.79C>A p.R27S | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100966483, COSV100966486; called by muse, mutect2, varscan2
- NDOR1 | c.1130C>G p.P377R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100788881, COSV61288897; called by muse, mutect2, varscan2
- NEB | c.9100G>T p.D3034Y | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99416962; called by muse, mutect2
- NIBAN1 | c.186+1G>A p.X62_splice | Splice Site (SNP) | VAF 10/106 reads (9%) | catalogued as COSV100836309; called by muse, mutect2
- NLRP13 | c.1550A>G p.Y517C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV100738079; called by muse, mutect2, varscan2
- NLRP3 | c.2297C>T p.P766L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as rs187819424, COSV100275498; called by muse, mutect2, varscan2
- NLRP8 | c.2558A>T p.Q853L | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1568466991, COSV99404868; called by muse, mutect2, varscan2
- NOC2L | c.2026G>T p.D676Y | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100497885, COSV58986677; called by muse, mutect2, varscan2
- NR3C2 | c.1697T>A p.L566Q | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV100678792; called by muse, mutect2, varscan2
- NUP214 | c.5702A>T p.N1901I | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100845180, COSV63909955; called by muse, mutect2, varscan2
- OR2T12 | c.58A>G p.R20G | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100527608; called by muse, mutect2, varscan2
- OR2T4 | c.493C>G p.P165A | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV100822413; called by muse, mutect2, varscan2
- OR4C16 | c.449C>A p.S150Y | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs749912465, COSV58941909; called by muse, mutect2, varscan2
- OR4D11 | c.223T>C p.S75P | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1251652344, COSV100506489; called by muse, mutect2, varscan2
- OR5B21 | c.61C>T p.L21F | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100835082, COSV100835114, COSV64482300; called by muse, mutect2, varscan2
- OR5P3 | c.215G>C p.G72A | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV60428923, COSV60428948; called by muse, mutect2, varscan2
- OR7A17 | c.433G>T p.V145F | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100541582; called by muse, mutect2, varscan2
- OR8G1 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.25); catalogued as COSV58382532; called by muse, mutect2, varscan2
- PAX1 | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101270232; called by muse, mutect2, varscan2
- PCDHA2 | c.1466T>A p.L489Q | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV100973686; called by muse, mutect2, varscan2
- PDCD11 | c.1498G>T p.G500W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100874266; called by muse, mutect2, varscan2
- PDE9A | c.1772A>G p.D591G | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV99371186; called by muse, mutect2, varscan2
- PDZRN3 | c.2438A>C p.E813A | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.084); catalogued as COSV99728051; called by muse, mutect2, varscan2
- PHF3 | c.1801C>A p.H601N | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100013012; called by muse, mutect2
- PLA2G4C | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.487); catalogued as rs138956741, CM1515258, COSV100843874; called by muse, mutect2, varscan2
- PLCG2 | c.1708C>G p.P570A | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV100842115, COSV63868171; called by muse, mutect2, varscan2
- PLCH1 | c.4591G>T p.V1531L (on ENST00000340059 / NM_001130960.2; = p.V1523L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100395966; called by muse, mutect2, varscan2
- PLEKHO1 | c.1145T>A p.L382Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99215166; called by muse, mutect2, varscan2
- PNLIPRP1 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100724293; called by muse, mutect2, varscan2
- PNLIPRP2 | c.1057A>G p.N353D | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.058); catalogued as COSV100077649; called by muse, mutect2
- PNMA2 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV101580600, COSV72908480; called by muse, mutect2, varscan2
- PRDM9 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV57012958, COSV99689947, COSV99691313; called by muse, mutect2, varscan2
- PRKD3 | c.1294C>A p.L432M | Missense Mutation (SNP) | VAF 89/138 reads (64%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as COSV99305808; called by muse, mutect2, varscan2
- PSG2 | c.122A>T p.Q41L | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as COSV101290464; called by muse, mutect2, varscan2
- PTPRC | c.1631T>G p.L544R | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61419427; called by muse, mutect2, varscan2
- PTPRC | c.2803A>T p.R935W | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100722246; called by muse, mutect2, varscan2
- PTPRJ | c.3547A>T p.T1183S | Missense Mutation (SNP) | VAF 65/102 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV101394669; called by muse, mutect2, varscan2
- PXDN | c.4169T>C p.L1390P | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.11); catalogued as COSV99412609; called by muse, mutect2, varscan2
- PXDN | c.1160C>A p.P387Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.728); catalogued as COSV99412281; called by muse, mutect2, varscan2
- RADX | c.1661G>T p.G554V | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100998783; called by muse, mutect2, varscan2
- RALYL | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101569074, COSV72822110; called by muse, mutect2, varscan2
- RANBP2 | c.1274-1G>T p.X425_splice | Splice Site (SNP) | VAF 77/238 reads (32%) | catalogued as COSV99311502; called by muse, mutect2, varscan2
- RGP1 | c.433G>T p.V145F | Missense Mutation (SNP) | VAF 63/84 reads (75%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.854); catalogued as COSV100960128; called by muse, mutect2, varscan2
- RIPOR2 | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99428714; called by muse, mutect2, varscan2
- ROR2 | c.620C>T p.T207I | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100995600; called by muse, mutect2, varscan2
- RYR3 | c.7117G>T p.G2373C (on ENST00000389232; = p.G2374C on NM_001036.6) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101212174, COSV66807458; called by muse, mutect2, varscan2
- SCN11A | c.1329T>G p.S443R | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.421); catalogued as COSV100181091; called by muse, mutect2, varscan2
- SEMA4F | c.1883G>T p.C628F | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100335825; called by muse, mutect2, varscan2
- SEMA5B | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as COSV99531089; called by muse, mutect2, varscan2
- SLAMF6 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100924845; called by muse, mutect2, varscan2
- SLC22A9 | c.373A>G p.I125V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV99654806; called by muse, mutect2, varscan2
- SLC26A11 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100755320; called by muse, mutect2, varscan2
- SLC26A7 | c.1255G>T p.G419* | Nonsense Mutation (SNP) | VAF 41/114 reads (36%) | catalogued as COSV99402853; called by muse, mutect2, varscan2
- SMAP1 | c.1372G>T p.G458C (on ENST00000370455 / NM_001044305.3; = p.G431C on NM_021940.5) | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100016713; called by muse, mutect2
- SNPH | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs144660706; called by muse, mutect2, varscan2
- SPAG5 | c.2919G>T p.M973I | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.406); catalogued as rs765126624, COSV99881781; called by muse, mutect2, varscan2
- SUN3 | c.592G>C p.E198Q | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.914); catalogued as COSV99813907; called by muse, mutect2, varscan2
- TESMIN | c.25G>T p.G9W | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as COSV99663444; called by muse, mutect2, varscan2
- TGM2 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.88); catalogued as COSV100821513; called by muse, mutect2, varscan2
- TLR4 | c.158C>A p.P53H (on ENST00000355622 / NM_138554.5; = p.P13H on NM_003266.4) | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100790616, COSV62924309; called by muse, mutect2, varscan2
- TRAT1 | c.278T>A p.M93K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV99849119; called by muse, mutect2, varscan2
- TRPC4AP | c.1115G>A p.R372K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.444); catalogued as COSV99327965; called by muse, mutect2, varscan2
- TTC31 | c.1244G>C p.C415S | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV99281993; called by muse, mutect2, varscan2
- TTN | c.34807G>A p.E11603K (on ENST00000591111; = p.E10676K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | PolyPhen probably damaging (0.987); catalogued as COSV100599749; called by muse, mutect2, varscan2
- TTN | c.24416C>T p.P8139L (on ENST00000591111; = p.P7212L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | PolyPhen possibly damaging (0.687); catalogued as rs1308450887, COSV100599750; called by muse, mutect2, varscan2
- TTN | c.23068C>T p.R7690* (on ENST00000591111; = p.R6763* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | catalogued as rs794727941, COSV59903910; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.2033C>T p.T678I (on ENST00000591111; = p.T632I on NM_003319.4) | Missense Mutation (SNP) | VAF 38/107 reads (36%) | PolyPhen benign (0.014); catalogued as rs1376628413, COSV100599753; called by muse, mutect2, varscan2
- TTN | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 31/67 reads (46%) | PolyPhen probably damaging (0.999); catalogued as rs1392286336, COSV59903999, COSV59927708; called by muse, mutect2, varscan2
- UBE2Q1 | c.343G>C p.V115L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV99427286; called by muse, mutect2, varscan2
- UNC5B | c.403T>G p.S135A | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV100100424; called by muse, mutect2, varscan2
- UTP20 | c.7022C>A p.T2341K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99881016; called by muse, mutect2, varscan2
- VCPIP1 | c.943T>A p.S315T | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.814); catalogued as COSV100125417; called by muse, mutect2, varscan2
- XPO7 | c.1999A>G p.T667A | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV99380902; called by muse, mutect2, varscan2
- ZCWPW2 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 5/38 reads (13%) | catalogued as COSV67497882; called by muse, mutect2, varscan2
- ZEB2 | c.1712T>C p.M571T | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.057); catalogued as COSV100355361; called by muse, mutect2, varscan2
- ZFHX4 | c.5078A>T p.Q1693L | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV99258711; called by muse, mutect2, varscan2
- ZNF112 | c.1109A>G p.H370R (on ENST00000337401 / NM_001083335.2; = p.H364R on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1325030968, COSV100495554; called by muse, mutect2, varscan2
- ZNF132 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as COSV99571029; called by muse, varscan2
- ZNF132 | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV54236297, COSV99571032; called by muse, varscan2
- ZNF132 | c.783G>C p.E261D | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.179); catalogued as COSV54234116, COSV99571034; called by muse, mutect2, varscan2
- ZNF304 | c.1291A>T p.N431Y | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV99988466; called by muse, mutect2, varscan2
- ZNF528 | c.15G>A p.Q5= | Splice Region (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100846626; called by muse, mutect2, varscan2
- ZNF831 | c.3876G>C p.R1292S | Missense Mutation (SNP) | VAF 69/313 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100925864; called by muse, mutect2, varscan2
- ZYX | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 117/280 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.351); catalogued as COSV100503606; called by muse, mutect2, varscan2
- FCGBP | c.6686C>T p.P2229L | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- KIR2DL1 | c.965C>A p.P322H | Missense Mutation (SNP) | VAF 73/299 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- PCLO | c.9712del p.E3238Nfs*26 | Frame Shift Del (DEL) | VAF 35/101 reads (35%) | called by mutect2, pindel, varscan2
- SOCS7 | c.1079C>G p.S360C | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TGM1 | c.1239_1244dup p.M413_D414dup | In Frame Ins (INS) | VAF 12/82 reads (15%) | called by mutect2, varscan2
- APOBEC3B | c.909G>C p.V303= | Silent (SNP) | VAF 28/257 reads (11%) | catalogued as COSV100213695; called by muse, mutect2, varscan2
- ARHGEF35 | c.846G>C p.V282= | Silent (SNP) | VAF 6/24 reads (25%) | called by mutect2, varscan2
- ATP10A | c.1647C>A p.A549= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV100790834, COSV100790987; called by muse, mutect2, varscan2
- ATXN10 | c.669C>T p.L223= | Silent (SNP) | VAF 29/156 reads (19%) | catalogued as rs1217796247, COSV53301544; called by muse, mutect2, varscan2
- AUTS2 | c.3495G>A p.T1165= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs964843078, COSV61390132; called by muse, mutect2, varscan2
- AVL9 | c.810A>T p.S270= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100594524; called by muse, mutect2, varscan2
- C11orf42 | c.250C>T p.L84= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV99791825; called by muse, mutect2, varscan2
- C12orf40 | c.471G>T p.V157= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100209737; called by muse, mutect2, varscan2
- C4orf50 | c.405A>G p.P135= (on ENST00000324058; = p.P1367= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 85/149 reads (57%) | catalogued as COSV100135672; called by muse, mutect2, varscan2
- C7orf50 | c.369G>A p.Q123= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV100657402; called by muse, mutect2, varscan2
- CNTN3 | c.1281C>A p.V427= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99723615; called by muse, mutect2, varscan2
- CNTNAP4 | c.207C>A p.G69= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100269904; called by muse, mutect2, varscan2
- DEPDC1 | c.1308G>A p.E436= | Silent (SNP) | VAF 78/130 reads (60%) | catalogued as COSV100920229, COSV63958685; called by muse, mutect2, varscan2
- DNAH9 | c.1809C>T p.N603= | Silent (SNP) | VAF 163/223 reads (73%) | catalogued as COSV99304691; called by muse, mutect2, varscan2
- DOCK11 | c.4560C>G p.T1520= | Silent (SNP) | VAF 37/58 reads (64%) | catalogued as COSV52236381, COSV99353163; called by muse, mutect2, varscan2
- DTX4 | c.291C>T p.N97= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs373681418; called by muse, mutect2, varscan2
- EXPH5 | c.4884C>T p.G1628= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as COSV99761149; called by muse, mutect2, varscan2
- GGTLC2 | c.336G>C p.T112= | Silent (SNP) | VAF 43/166 reads (26%) | catalogued as rs139520107, COSV101312195; called by muse, mutect2, varscan2
- H3-4 | c.399G>T p.G133= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100797364; called by muse, mutect2, varscan2
- H4C7 | c.258C>A p.A86= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as COSV99769035; called by muse, mutect2, varscan2
- INHA | c.72G>A p.L24= | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV99216406; called by muse, mutect2, varscan2
- IVL | c.321G>A p.Q107= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs767490137, COSV100908129, COSV64215723; called by muse, mutect2, varscan2
- KALRN | c.507G>A p.T169= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs765186794, COSV53752662; called by muse, mutect2, varscan2
- KCNB2 | c.1152T>C p.Y384= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as COSV101578692; called by muse, mutect2, varscan2
- KCNK1 | c.348C>T p.S116= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100785863; called by muse, mutect2
- KRTAP1-3 | c.459C>T p.C153= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs753406860, COSV60337217; called by muse, mutect2, varscan2
- LILRA1 | c.780G>A p.E260= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as rs1414501833, COSV99251775; called by muse, mutect2, varscan2
- LRRTM4 | c.1239A>C p.A413= | Silent (SNP) | VAF 41/71 reads (58%) | catalogued as COSV101297446; called by muse, mutect2, varscan2
- MAGEC1 | c.2370T>C p.L790= | Silent (SNP) | VAF 74/114 reads (65%) | catalogued as COSV99595086; called by muse, mutect2, varscan2
- MAGEC1 | c.2739C>T p.D913= | Silent (SNP) | VAF 68/107 reads (64%) | catalogued as rs370841892, COSV99595087; called by muse, mutect2, varscan2
- MROH2B | c.1197C>A p.V399= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV101270587; called by muse, mutect2, varscan2
- MYH13 | c.1326C>T p.V442= | Silent (SNP) | VAF 56/153 reads (37%) | catalogued as COSV99352793; called by muse, mutect2, varscan2
- NDST4 | c.1404C>A p.I468= | Silent (SNP) | VAF 40/51 reads (78%) | catalogued as COSV52131151, COSV52137605; called by muse, mutect2, varscan2
- NEXMIF | c.2262C>A p.S754= | Silent (SNP) | VAF 22/36 reads (61%) | catalogued as COSV99280027; called by muse, mutect2, varscan2
- NOTCH1 | c.3375G>C p.A1125= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99486110; called by muse, mutect2, varscan2
- NPAP1 | c.675C>T p.A225= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs751804517, COSV100274922; called by muse, mutect2, varscan2
- OR11H1 | c.402G>A p.L134= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs1256697221; called by mutect2, varscan2
- OR2A2 | c.171C>A p.P57= | Silent (SNP) | VAF 108/243 reads (44%) | catalogued as COSV101286624; called by muse, mutect2, varscan2
- OR2T4 | c.237T>C p.L79= | Silent (SNP) | VAF 93/231 reads (40%) | catalogued as rs1416267062, COSV100822412; called by muse, mutect2, varscan2
- OR5M10 | c.471C>T p.L157= | Silent (SNP) | VAF 23/100 reads (23%) | catalogued as COSV101595865; called by muse, mutect2, varscan2
- OR5T2 | c.234C>T p.L78= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as rs775999147, COSV100506854; called by muse, mutect2
- OR8H3 | c.162C>A p.L54= | Silent (SNP) | VAF 69/420 reads (16%) | catalogued as COSV100538800; called by muse, mutect2, varscan2
- OR8K3 | c.594A>T p.I198= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV100449697; called by muse, mutect2, varscan2
- OSBPL7 | c.1509G>T p.P503= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV99136580; called by muse, mutect2, varscan2
- PCDH17 | c.558C>A p.R186= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100931489; called by muse, mutect2
- PCDHA13 | c.543C>T p.D181= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV99165224; called by muse, mutect2, varscan2
- POLR3A | c.2208G>A p.L736= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100965566; called by muse, mutect2, varscan2
- PRDM9 | c.2265G>T p.R755= | Silent (SNP) | VAF 40/81 reads (49%) | catalogued as COSV99689949; called by muse, varscan2
- PRKDC | c.9858C>T p.C3286= | Silent (SNP) | VAF 35/122 reads (29%) | catalogued as rs750682248, COSV100039016; called by muse, mutect2, varscan2
- QSOX1 | c.741C>A p.S247= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV100852823, COSV62579815; called by muse, mutect2, varscan2
- RBM6 | c.1644C>T p.N548= | Silent (SNP) | VAF 29/160 reads (18%) | catalogued as COSV56483007, COSV99804796; called by muse, mutect2, varscan2
- RBP5 | c.156G>A p.V52= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV99866640; called by muse, mutect2, varscan2
- RIPK4 | c.57G>T p.A19= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100204737; called by muse, mutect2, varscan2
- RITA1 | c.777G>A p.G259= | Silent (SNP) | VAF 34/53 reads (64%) | catalogued as COSV55321567; called by muse, mutect2, varscan2
- ROBO1 | c.762C>T p.A254= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs762931858, COSV71392013; called by muse, mutect2
- SLC35F1 | c.774A>G p.A258= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100837646; called by muse, mutect2, varscan2
- SOCS4 | c.1095G>A p.K365= | Silent (SNP) | VAF 45/95 reads (47%) | catalogued as COSV100216073; called by muse, mutect2, varscan2
- SORCS2 | c.567G>A p.T189= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs575501301, COSV61164003; called by muse, mutect2, varscan2
- STARD8 | c.1284C>A p.T428= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV99366369; called by muse, mutect2, varscan2
- SYNE2 | c.3744A>G p.G1248= | Silent (SNP) | VAF 113/234 reads (48%) | catalogued as COSV100647022; called by muse, varscan2
- SYT4 | c.765G>A p.G255= | Silent (SNP) | VAF 24/36 reads (67%) | catalogued as COSV54900876; called by muse, mutect2, varscan2
- TAS2R31 | c.156G>A p.A52= | Silent (SNP) | VAF 42/226 reads (19%) | catalogued as rs577784067, COSV101114357; called by muse, mutect2, varscan2
- TEKT3 | c.927C>G p.L309= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100106871; called by muse, mutect2
- TEX10 | c.285C>T p.H95= | Silent (SNP) | VAF 66/256 reads (26%) | catalogued as rs750538181, COSV100887636; called by muse, mutect2, varscan2
- TNR | c.99G>T p.L33= | Silent (SNP) | VAF 60/138 reads (43%) | catalogued as COSV99688240; called by muse, mutect2, varscan2
- TRGV2 | c.276A>T p.T92= | Silent (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2, varscan2
- TRIM22 | c.1146G>A p.K382= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV101181248; called by muse, mutect2, varscan2
- TTN | c.66957C>A p.I22319= (on ENST00000591111; = p.I14895= on NM_003319.4) | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100599747, COSV59958093; called by muse, mutect2, varscan2
- TTN | c.46767T>C p.I15589= (on ENST00000591111; = p.I8165= on NM_003319.4) | Silent (SNP) | VAF 109/223 reads (49%) | catalogued as COSV100599748; called by muse, mutect2, varscan2
- TTN | c.1230C>T p.A410= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV100599757; called by muse, mutect2, varscan2
- WDTC1 | c.1425G>A p.L475= (on ENST00000319394 / NM_001276252.2; = p.L474= on NM_015023.5) | Silent (SNP) | VAF 27/40 reads (68%) | catalogued as rs1187216401, COSV100088608; called by muse, mutect2, varscan2
- ZNF107 | c.1446C>A p.T482= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV100788272; called by muse, mutect2
- ZNF419 | c.60A>C p.T20= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV99691867; called by muse, mutect2, varscan2
- CD300LD | chr17:74592544 C>T | 5'Flank (SNP) | VAF 8/39 reads (21%) | catalogued as rs754734146; called by muse, mutect2, varscan2
- OR2W5 | n.899C>A | RNA (SNP) | VAF 28/127 reads (22%) | catalogued as rs773435808; called by muse, mutect2, varscan2
- TOR1AIP2 | c.-146-12057T>A | Intron (SNP) | VAF 26/103 reads (25%) | catalogued as COSV100857313; called by muse, mutect2, varscan2
